Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MM, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MM-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTE

Primary malignant melanoma back. Now axilla LNs. FNAB positive.

SPECIMEN INFORMATION

Axillary dissection.

MACROSCOPIC DESCRIPTION

"Left axillary contents". A mass of fibrofatty connective tissue and skeletal muscle 170 x 120 x 60mm. The specimen was examined for lymph nodes. There is a large lymph node 70 x 55 x 40mm. On sectioning the lymph node appears extensively infiltrated by tumour.

A-C. One full face section through largest node infiltrated by tumour.

D-E. One node bisected longitudinally.

F. One node in two sections.

G. One node in two sections.

H. One node in two sections.

J. Four nodes

K. Three nodes.

L. Two nodes.

100-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary

C77.3

hw 8/24/11

MICROSCOPIC REPORT

"Left axillary contents".

The large node is almost totally replaced by malignant tumour consistent with metastatic malignant melanoma. Staining is positive for S100 and Melan-A but negative for HMB45.

There is no definite extranodal extension.

The other 13 lymph nodes are negative for malignancy.

Electronic signature

Verified by:

DIAGNOSIS

Lymph node - metastatic malignant melanoma

[page 2 of 2]
Requested by: N/A

MRN/Name
Location
Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

SUMMARY / KEY WORDS

lymph node - malignant melanoma, metastatic
Haematopathology resection

Source: NCI Genomic Data Commons file 9bce8a82-9f37-434f-afd4-ea20074ceda2 (TCGA-EE-A2MM.B23219CD-5473-42D0-A0BB-49EC8A1756FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).